Somatic mutation profile of tumor specimen TARGET-20-PASCFW-09A (aliquot TARGET-20-PASCFW-09A-01D) from TARGET case TARGET-20-PASCFW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (733 days).
Specimen TARGET-20-PASCFW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60db51aa-0952-4760-af8f-4c9468f6f3ac.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASCFW-14A (Bone Marrow Normal), aliquot TARGET-20-PASCFW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/146057ea-2301-4afb-b6ae-450cff09c428

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2054G>A p.R685H (on ENST00000460911 / NM_001203247.2; = p.R690H on NM_004456.5) | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554481435, COSV57446082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
